Somatic mutation profile of tumor specimen MP2PRT-PAVUCJ-TMP1-A (aliquot MP2PRT-PAVUCJ-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVUCJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (965 days).
Specimen MP2PRT-PAVUCJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7c28c86-c196-4ccc-a52c-55f7b58895cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUCJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUCJ-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/989c0fdd-31b5-4359-bfb8-26c716209393

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf54 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs1225468317, COSV101552143; called by muse, mutect2
- GRM8 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 29/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772324014, COSV58803533; called by muse, mutect2
- HS2ST1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs1270538841; called by muse, mutect2, varscan2
- NT5DC3 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1372160503, COSV101231021; called by muse, mutect2
- TMEM201 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751174516; called by muse, mutect2
- ZFHX2 | c.5494C>T p.R1832W | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1407291888; called by muse, mutect2
- CLUAP1 | c.1169_1171delinsTT p.S390Ffs*51 | Frame Shift Del (DEL) | VAF 53/543 reads (10%) | called by pindel, varscan2*
- KISS1R | c.230C>A p.T77N | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NDST3 | c.887G>C p.R296T | Missense Mutation (SNP) | VAF 39/351 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TYR | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 117/368 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- UBA2 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNC80 | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF546 | c.985T>C p.Y329H | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- HBM | c.303A>T p.L101= | Silent (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- MARCHF3 | c.433C>T p.L145= | Silent (SNP) | VAF 50/426 reads (12%) | called by muse, mutect2, varscan2
- MPEG1 | c.1293C>T p.N431= | Silent (SNP) | VAF 37/285 reads (13%) | called by muse, mutect2, varscan2
- MYH1 | c.933C>T p.Y311= | Silent (SNP) | VAF 25/216 reads (12%) | catalogued as rs571999841, COSV56849298; called by muse, mutect2, varscan2
- WNT16 | c.696G>A p.V232= (on ENST00000222462 / NM_057168.2; = p.V222= on NM_016087.2) | Silent (SNP) | VAF 33/282 reads (12%) | called by muse, mutect2, varscan2
